Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JS, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JS-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
Carcinoma, invasive papillary, introduced nos
(invasive) 8503/3
Site: breast, nos C50.9 3/11/11
lw

page 1 / 2

Department of Cancer Pathology

copy No. 2

Date:

Examination: Intraoperative examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – right breast.

Unit in charge:

Physician in charge:

Material collected on

Material received on:

Expected time of examination: 20 minutes (from receipt of the material)

Clinical diagnosis: Suspected cancer of the right breast. Lesion on the boundary of the upper quadrants.

Examination performed on

Result of intraoperative examination:

Carcinoma probabilliter invasivum.

Final diagnosis after paraffin specimens are analysed.

UUID:0EAS7ABF-E3DA-4862-BAB8-A6E36408AC42

Compliance validated by:

Examination performed on:

Macroscopic description:

Surgical specimen sized 5 x 4 x 2 cm with a skin flap of 4 x 0.5 cm.

Minimum side margin 0.2 cm.

Result of intraoperative examination:

Carcinoma papillare probabilliter invasivum.

Foci DCIS typus cribrusos cum atypia gradus levioris ad mediocrum sine necrosis.

Final diagnosis after immunohistochemical tests.

ICPAA Discrepancy		X
Excluded (Yes/No)	QUATIFIED	DISQUALIFIED
Reviewed Initial	Date Reviewed: 3/11/11	

Compliance validated by:

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 0)

Compliance validated by:

Examination performed on:

[page 2 of 2]
Examination: Intraoperative examination

page 2 / 2

Examination No.

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on:

Histopathological diagnosis:

Carcinoma papillare probabiliter invasivum NHG1 (2 + 2 +1/0 mitoses/ 10 HPF, visual area diameter: 0.55 m).

Corresponds to invasive papillary carcinoma of the right breast.

Solitary foci of DCIS (cribrate type with medium nuclear atypia, without necrosis).

The immunohistochemical test showed the absence of a myoepithelial cell stratum around the foci of the invasive lesion (p63-, SMA'). The cells show negative reaction with CK5/6. Cytokeratin 7 present in part of the cells.

Compliance validated by:

Examination performed on:

Supplementary test

Expression of the Ki67 proliferation antigen showed in 5% of cellular nuclei (20% in hot spots)

Compliance validated by

Source: NCI Genomic Data Commons file df5ff237-957c-4216-8042-d8053e57f45a (TCGA-D8-A1JS.0EA57ABF-E3DA-4862-BAB8-A6E36408AC42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).